Somatic mutation profile of tumor specimen TCGA-23-2077-01A (aliquot TCGA-23-2077-01A-01W-0722-08) from TCGA case TCGA-23-2077, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.3 years (16,552 days).
Specimen TCGA-23-2077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c7f7ad6-1c83-4648-a6ba-b820865d40bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2077-10A (Blood Derived Normal), aliquot TCGA-23-2077-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef79f54-d813-490c-87f0-e281447ec960

The open-access MAF lists 114 somatic variants for this specimen: 88 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 24, Nonsense Mutation 5, Splice Site 2, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GIGYF2 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as rs748538823, COSV65247766; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 144/232 reads (62%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB1 | c.2165G>T p.G722V | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947626, COSV55952023; called by muse, mutect2, varscan2
- ABCB4 | c.1315G>T p.V439F | Missense Mutation (SNP) | VAF 23/313 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs760759247, COSV99710149; called by muse, mutect2
- ABCB5 | c.3359T>G p.V1120G (on ENST00000404938 / NM_001163941.2; = p.V675G on NM_178559.6) | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328004; called by muse, mutect2
- ABCF3 | c.1553A>T p.E518V | Missense Mutation (SNP) | VAF 414/968 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV53051799; called by muse, mutect2, varscan2
- ADGRE3 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53729256; called by muse, mutect2, varscan2
- ALG10B | c.42C>A p.S14R | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs376126647; called by muse, mutect2, varscan2
- ALG12 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 10/88 reads (11%) | PolyPhen possibly damaging (0.804); catalogued as COSV100427072; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV50054989; called by muse, mutect2, varscan2
- BAZ1B | c.647A>T p.K216I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV59989751; called by muse, mutect2, varscan2
- C1R | c.673C>T p.P225S (on ENST00000536053 / NM_001354346.2; = p.P211S on NM_001733.7) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101599218; called by muse, mutect2
- C1orf141 | c.817C>G p.P273A | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as rs761435372, COSV63992352; called by muse, mutect2, varscan2
- CAPZA3 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56849081, COSV56850605; called by muse, mutect2, varscan2
- CBFB | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 10/139 reads (7%) | catalogued as COSV52000547; called by muse, mutect2
- CD300E | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 48/389 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV60790117; called by muse, mutect2, varscan2
- CDC42 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 20/532 reads (4%) | catalogued as COSV100212539; called by muse, mutect2
- CDH22 | c.1523G>A p.C508Y | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1224413966, COSV100952814; called by muse, mutect2
- COL9A2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.83); catalogued as COSV65607297; called by muse, mutect2, varscan2
- COLGALT2 | c.630C>G p.G210= | Splice Region (SNP) | VAF 7/128 reads (5%) | catalogued as COSV100730560, COSV62298433; called by muse, mutect2
- CSF1 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 22/649 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as COSV100294424; called by muse, mutect2
- CTCFL | c.174C>A p.D58E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV54772047; called by muse, mutect2, varscan2
- DENND2A | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV52049108; called by muse, mutect2, varscan2
- DNMT3B | c.2155G>T p.V719L | Missense Mutation (SNP) | VAF 71/492 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52416305; called by muse, mutect2, varscan2
- DYRK1B | c.216G>C p.Q72H | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs772161282, COSV55682329; called by muse, mutect2, varscan2
- EDIL3 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99675743; called by muse, mutect2
- EIF2B4 | c.745T>C p.S249P (on ENST00000347454 / NM_001034116.2; = p.S248P on NM_015636.3) | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV99277453; called by muse, mutect2
- EIF3E | c.614T>A p.L205H | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV55202109; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2599G>T p.G867C | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV100348984; called by muse, mutect2
- ELF3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV62837797; called by muse, mutect2, varscan2
- ELMO2 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51682069; called by muse, mutect2, varscan2
- ESRP2 | c.1635G>C p.E545D (on ENST00000565858 / NM_001365264.1; = p.E535D on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.028); catalogued as COSV52172673; called by muse, mutect2, varscan2
- FABP3 | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs768005655, COSV100703933; called by muse, mutect2
- FAT3 | c.11822G>A p.R3941H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV53091017; called by muse, mutect2, varscan2
- FBXW11 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 25/441 reads (6%) | catalogued as COSV51612417; called by muse, mutect2
- GTF3C1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100649245; called by muse, mutect2
- HSPG2 | c.7064G>C p.G2355A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65970110; called by muse, mutect2, varscan2
- HUWE1 | c.9687C>G p.I3229M | Missense Mutation (SNP) | VAF 18/435 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99471577; called by muse, mutect2
- LRP2 | c.5900C>A p.A1967E | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV55546652; called by muse, mutect2, varscan2
- LYST | c.10568T>C p.V3523A | Missense Mutation (SNP) | VAF 21/510 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV101088942; called by muse, mutect2
- MAST1 | c.2615A>G p.D872G | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.184); catalogued as COSV52243309; called by muse, mutect2
- MICAL2 | c.2598G>C p.K866N | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as COSV56318359; called by muse, mutect2, varscan2
- MMP8 | c.630C>G p.N210K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99368366; called by muse, mutect2
- MROH2B | c.1582G>C p.A528P | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV68182407; called by muse, mutect2, varscan2
- MTHFD1L | c.2859G>A p.M953I | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.138); catalogued as COSV100944984, COSV66226508; called by muse, mutect2
- MTX2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV50887630; called by muse, mutect2, varscan2
- NPIPB3 | c.338C>G p.T113S (on ENST00000542817; = p.T329S on NM_130464.3) | Missense Mutation (SNP) | VAF 108/632 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV70019065; called by muse, varscan2
- NRAP | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.842); catalogued as COSV100748379; called by muse, mutect2
- OR10A7 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58277940; called by muse, mutect2
- OR12D3 | c.495T>A p.S165R | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101011201, COSV65830105; called by muse, mutect2
- OR14K1 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 56/736 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV99315086; called by muse, mutect2
- OR2A7 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71827391; called by muse, mutect2, varscan2
- OR5K4 | c.864T>A p.S288R | Missense Mutation (SNP) | VAF 66/774 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100721329; called by muse, mutect2
- OR5V1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 160/538 reads (30%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.969); catalogued as rs772202001, COSV65826988; called by muse, mutect2, varscan2
- OVGP1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63857986; called by muse, mutect2, varscan2
- PAQR5 | c.912C>G p.I304M | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV61817642; called by muse, mutect2, varscan2
- PARP14 | c.4873A>G p.S1625G | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101506259; called by muse, mutect2
- PCYOX1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs149802301; called by muse, mutect2, varscan2
- PGBD5 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as rs1458079598, COSV58410984; called by muse, mutect2, varscan2
- PKP1 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 41/676 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99825150; called by muse, mutect2
- PLEKHA6 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs757944921, COSV55333618; called by muse, mutect2
- PNLIPRP3 | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65047398; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57963752; called by muse, mutect2, varscan2
- PROM2 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1339652382, COSV58297427; called by muse, mutect2, varscan2
- PXDN | c.3527A>C p.Y1176S | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV53229561; called by muse, mutect2, varscan2
- RIMS4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1375008483, COSV65719414; called by muse, mutect2, varscan2
- RNF32 | c.879C>A p.C293* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100311344; called by muse, mutect2, varscan2
- SATL1 | c.752A>C p.Q251P (on ENST00000395409; = p.Q438P on NM_001012980.2) | Missense Mutation (SNP) | VAF 29/417 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV100260763; called by muse, mutect2
- SF3B4 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99641075; called by muse, mutect2
- SHCBP1 | c.1110G>T p.L370F | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); catalogued as COSV100317211; called by muse, mutect2
- SNURF | c.110+1G>A p.X37_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100578082; called by muse, mutect2, varscan2
- SOGA3 | c.722dup p.G242Rfs*17 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs778091058; called by pindel, varscan2
- SPHKAP | c.4792C>A p.P1598T (on ENST00000392056 / NM_001142644.2; = p.P1569T on NM_030623.3) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.516); catalogued as COSV60872651, COSV60890561; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | PolyPhen benign (0.103); catalogued as COSV60325182; called by mutect2, varscan2
- TAF6L | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV53667660; called by mutect2, varscan2
- TFAP2D | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs780379700, COSV50410964; called by muse, varscan2
- THOC2 | c.2924C>G p.T975R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55542819; called by muse, mutect2, varscan2
- TRAPPC9 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 18/596 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.903); catalogued as COSV101227154; called by muse, mutect2
- TSEN54 | c.1351G>C p.D451H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV51344688; called by muse, mutect2, varscan2
- UNC13A | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53191341; called by muse, mutect2, varscan2
- ZFYVE26 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1566894893, COSV61325896; called by muse, mutect2, varscan2
- ZGLP1 | c.765G>C p.K255N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV67059350; called by muse, mutect2, varscan2
- ZNF670 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV63607851; called by muse, mutect2, varscan2
- ACTR3B | c.1158_1161+13del p.X386_splice | Splice Site (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- DNAH11 | c.2047del p.E683Kfs*20 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- ECD | c.-3_13del | Translation Start Site (DEL) | VAF 57/524 reads (11%) | called by mutect2, pindel
- HLA-DMB | c.133_141del p.S45_N47del | In Frame Del (DEL) | VAF 76/229 reads (33%) | called by mutect2, pindel, varscan2
- NEK10 | c.1823A>T p.E608V | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- AFAP1 | c.1539T>C p.G513= | Silent (SNP) | VAF 10/222 reads (5%) | catalogued as COSV100631334; called by muse, mutect2
- ASAP1 | c.2811A>G p.G937= | Silent (SNP) | VAF 39/462 reads (8%) | catalogued as COSV63046105; called by muse, mutect2
- BPIFB3 | c.186T>C p.A62= | Silent (SNP) | VAF 78/167 reads (47%) | catalogued as COSV64957019; called by muse, mutect2, varscan2
- CEMIP2 | c.45A>G p.Q15= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV65486237; called by muse, mutect2, varscan2
- CLDN18 | c.129G>C p.V43= | Silent (SNP) | VAF 16/404 reads (4%) | catalogued as COSV99480743; called by muse, mutect2
- COL4A4 | c.5040C>A p.I1680= | Silent (SNP) | VAF 64/682 reads (9%) | catalogued as COSV61630617; called by muse, mutect2
- CSMD2 | c.4002G>A p.E1334= | Silent (SNP) | VAF 84/248 reads (34%) | catalogued as COSV53892300; called by muse, mutect2, varscan2
- DIP2B | c.2364T>C p.D788= | Silent (SNP) | VAF 78/164 reads (48%) | catalogued as COSV99998273; called by muse, mutect2, varscan2
- DNMT1 | c.999G>A p.T333= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs772293711, COSV100532281; called by mutect2, varscan2
- EPHB2 | c.426A>C p.A142= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV65860839; called by muse, mutect2, varscan2
- ERMP1 | c.2043G>C p.P681= | Silent (SNP) | VAF 46/494 reads (9%) | catalogued as COSV53036719; called by muse, mutect2
- GMPR | c.702T>A p.A234= | Silent (SNP) | VAF 85/900 reads (9%) | catalogued as COSV52472656; called by muse, mutect2
- LCE2B | c.330C>T p.C110= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as rs749402088, COSV64227519; called by muse, mutect2, varscan2
- MAN2B1 | c.837G>T p.V279= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV55470913; called by muse, mutect2, varscan2
- MUC16 | c.4629G>A p.T1543= | Silent (SNP) | VAF 242/1091 reads (22%) | catalogued as rs1180806852, COSV101199341; called by muse, mutect2, varscan2
- OR8K3 | c.60C>A p.I20= | Silent (SNP) | VAF 102/785 reads (13%) | catalogued as COSV57130876, COSV57131041; called by muse, mutect2, varscan2
- POGLUT3 | c.1128C>T p.T376= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as rs183206038, COSV100052754, COSV60212066; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1242T>G p.A414= | Silent (SNP) | VAF 32/623 reads (5%) | catalogued as COSV99424616; called by muse, mutect2
- RYR3 | c.2040G>T p.L680= | Silent (SNP) | VAF 20/463 reads (4%) | catalogued as COSV101212451; called by muse, mutect2
- SLC25A10 | c.369C>G p.V123= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV58970042; called by muse, mutect2
- SLC5A11 | c.888T>G p.T296= | Silent (SNP) | VAF 91/850 reads (11%) | catalogued as COSV100762735; called by muse, mutect2
- THBD | c.1251C>T p.C417= | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as rs1568665927, COSV65703131; called by muse, mutect2
- TTLL5 | c.1461T>A p.P487= | Silent (SNP) | VAF 80/273 reads (29%) | catalogued as COSV54030278; called by muse, mutect2, varscan2
- UBL7 | c.1033C>T p.L345= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV100795369; called by muse, mutect2
- AC092718.9 | chr16:81156920 C>T | 3'Flank (SNP) | VAF 8/69 reads (12%) | catalogued as rs1351854547; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16940A>C | Intron (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
